Gene-level copy-number profile of tumor specimen TCGA-2G-AAHE-01A from TCGA case TCGA-2G-AAHE, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 32.7 years (11,940 days).
Specimen TCGA-2G-AAHE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f4ec0efc-69f1-4192-aca1-99676cfa05c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/b848d4ea-162d-436d-97a3-00989d13462a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 1,011; copy number 2: 16,055; copy number 3: 18,587; copy number 4: 15,868; copy number 5: 4,432; copy number 6: 1,531; copy number 7: 467; copy number 8: 401; copy number 9: 46.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 914 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,672,823–103,501,895, 912 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:31,363,481–31,369,301, 2 genes, copy number 7: LINC02387, U6.

Autosomal genes at a single copy (total copy number 1): 1,011. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
